Somatic mutation profile of tumor specimen 0DP6HY from CCDI case PBCDIA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 11.0 years (4,032 days).
Specimen 0DP6HY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1820184b-8d9d-417a-9c74-da6d10cfbd78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP6HN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d92d35a7-d162-4595-a2f1-e5bf17201c6a

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, Silent 2, Nonsense Mutation 1, 5'UTR 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSN | c.3743C>T p.T1248M | Missense Mutation (SNP) | VAF 69/446 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs755975338; called by muse, mutect2, varscan2
- EPHA10 | c.2134G>A p.V712I | Missense Mutation (SNP) | VAF 89/391 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753810317, COSV57626608; called by muse, mutect2, varscan2
- FAM83H | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 159/395 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66353980; called by muse, mutect2, varscan2
- TAF6 | c.1342T>A p.Y448N | Missense Mutation (SNP) | VAF 369/688 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100612629; called by muse, mutect2, varscan2
- TRIM54 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 31/708 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs1452726256; called by muse, mutect2
- CAPN6 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 130/661 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIS3L2 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 279/658 reads (42%) | called by muse, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 48/984 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- WFDC8 | c.588C>T p.V196= | Splice Region (SNP) | VAF 359/1116 reads (32%) | called by muse, mutect2, varscan2
- NUDT3 | c.372C>T p.D124= | Silent (SNP) | VAF 57/464 reads (12%) | catalogued as rs776425812, COSV70444530; called by muse, mutect2, varscan2
- SOBP | c.1107T>C p.P369= | Silent (SNP) | VAF 160/357 reads (45%) | called by muse, mutect2, varscan2
- ADH6 | c.828+41C>A | Intron (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 9/185 reads (5%) | called by muse, mutect2
- DDX3X | c.763-71_763-70insTTCATCACAACATAATTCCCTTTTGTAATTTATAGATTACAAAAG | Intron (INS) | VAF 1/126 reads (1%) | called by muse*, mutect2
- ID1 | c.*45A>G | 3'UTR (SNP) | VAF 275/814 reads (34%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 17/140 reads (12%) | called by muse, varscan2
- RNF32 | c.451-31G>A | Intron (SNP) | VAF 16/434 reads (4%) | called by muse, mutect2
